Gene-level copy-number profile of tumor specimen TCGA-98-A53B-01A from TCGA case TCGA-98-A53B, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 69.5 years (25,390 days).
Specimen TCGA-98-A53B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.d934304f-529f-46b9-9bb1-e8ed214ad077.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-98-A53B-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d466aeca-2755-4293-91c7-c64742b233b7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 153; copy number 1: 495; copy number 2: 20,269; copy number 3: 14,451; copy number 4: 17,009; copy number 5: 5,207; copy number 6: 219; copy number 7: 772; copy number 8: 402; copy number 9: 31; copy number 10: 148; copy number 11: 29; copy number 12: 11; copy number 13: 466; copy number 14: 14; copy number 15: 32; copy number 17: 34; copy number 19: 4; copy number 20: 29; copy number 29: 11; copy number 38: 31.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-98-A53B-01A-11D-A25M-01): tumor purity 0.36, ploidy 3.31, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 153 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,096–305,474, 10 genes: BNIP3P41, ZNF595, AC253576.1, ZNF718, AC253576.2, AC108475.1, ZNF876P, AC079140.3, AC079140.5, ZNF732.
- chr8:4,317,388–4,788,584, 4 genes: AC027251.1, AC010941.1, AC022068.1, PAICSP4.
- chr9:19,789,179–30,832,225, 139 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7,434 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:237,042,184–237,833,988, 1 gene, copy number 5 (within-gene range 4–5): RYR2.
- chr1:237,471,119–241,357,230, 54 genes, copy number 5 (within-gene range 4–5): MIR4428, AL442065.1, AL359924.1, ZP4, AL590396.1, MTCO1P38, AL590396.2, AL590396.3, MTRNR2L11, MTCYBP15, MTND6P15, MTND5P18, YWHAQP9, AL356010.2, AL356010.1, RNU6-725P, LINC01139, AL359551.1, KRT18P32, MIPEPP2, AL583825.1, AL590135.1, AC093426.2, AC093426.1, CHRM3, CHRM3-AS2, CHRM3-AS1, AL356361.2, AL356361.1, AL356361.3, RPS7P5, FMN2, AL359918.1, Y_RNA, ADH5P3, AL359918.2, Y_RNA, AL590490.1, GREM2, AL358176.1, AL358176.2, AL358176.4, AL358176.3, RNU5F-8P, AL358176.5, Y_RNA, AL365184.2, AL365184.1, THAP12P8, RGS7, RFKP1, HNRNPA1P42, AL590682.1, MIR3123.
- chr2:41,716,133–44,361,862, 59 genes, copy number 5: AC009413.1, LDHAP3, RPS12P4, Y_RNA, LINC01913, RNU4-63P, LINC01914, C2orf91, AC013480.1, PKDCC, EML4-AS1, EML4, COX7A2L, AC025750.2, KCNG3, VDAC1P13, RPS13P3, MTA3, Metazoa_SRP, AC025750.1, AC074375.1, RNU6-137P, OXER1, HAAO, FTOP1, CHORDC1P1, AC016735.1, LINC01819, LINC02590, RNU6-242P, LINC02580, AC010883.2, AC010883.3, ZFP36L2, LINC01126, AC010883.1, THADA, RNU6-958P, RN7SL531P, Y_RNA, PLEKHH2, C1GALT1C1L, AC011242.1, RN7SKP66, DYNC2LI1, ABCG5, ABCG8, LRPPRC, RNU6-1048P, RN7SL455P, AC019129.1, RNU6-566P, PDSS1P2, AC019129.2, PPM1B, AC013717.1, RPL12P19, SLC3A1, PREPL.
- chr2:46,003,942–47,907,810, 50 genes, copy number 5: RPL26P15, AC017006.2, AC017006.1, RPL36AP14, Metazoa_SRP, EPAS1, LINC01820, LINC02583, AC016912.2, AC016912.1, RN7SL817P, TMEM247, ATP6V1E2, RHOQ, RHOQ-AS1, PIGF, CRIPT, AC020604.1, LINC01118, SOCS5, LINC01119, AC016722.1, AC016722.2, MCFD2, TTC7A, AC093732.2, AC093732.1, STPG4, AC073283.3, AC073283.1, CALM2, EPCAM-DT, AC073283.2, BCYRN1, EPCAM, RN7SKP119, MIR559, Metazoa_SRP, MSH2, KCNK12, MSH2-OT1, AC079250.1, MSH6, NME2P2, AC006509.1, U6, FBXO11, RPL36AP15, RPS27AP7, AC079807.1.
- chr2:47,939,738–47,990,526, 2 genes, copy number 5: PPIAP62, VN1R18P.
- chr2:66,235,377–68,110,948, 24 genes, copy number 5: AC118345.1, AC092669.1, MIR4778, LINC01873, MEIS1-AS3, MEIS1, MEIS1-AS2, LINC01798, LINC01797, DNMT3AP1, AC009474.1, LINC01799, LINC01628, AC007403.1, LINC01828, LINC01829, AC023115.1, ETAA1, LINC02831, AC007422.1, AC010987.1, LINC01812, FBXL12P1, C1D.
- chr3:93,843,764–104,063,582, 141 genes, copy number 6–8 (broad region; genes not listed).
- chr3:115,802,363–117,139,389, 1 gene, copy number 5 (within-gene range 4–5): LSAMP.
- chr3:116,360,024–117,997,592, 16 genes, copy number 5: LSAMP-AS1, LINC00903, RN7SL582P, BZW1P2, TUSC7, AC108713.1, MIR4447, AC069504.1, LINC00901, RNU5E-8P, PTMAP8, RNU6-1200P, AC092691.1, AC092691.2, LINC02024, AC092691.3.
- chr3:130,212,823–189,325,304, 959 genes, copy number 5–8 (broad region; genes not listed).
- chr3:189,829,922–198,222,513, 211 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr5:58,198–19,234,487, 353 genes, copy number 7 (broad region; genes not listed).
- chr5:20,606,710–45,895,970, 353 genes, copy number 8–12 (broad region; genes not listed).
- chr6:51,615,299–54,266,280, 67 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr6:96,521,595–99,589,899, 34 genes, copy number 9–14: UFL1, FHL5, RPS7P8, RNU4-70P, TYMSP1, AL355143.1, EEF1GP6, AL033379.1, GPR63, NDUFAF4, RN7SL509P, KLHL32, MMS22L, AL589740.1, AL080316.1, MIR2113, EIF4EBP2P3, AL590727.1, AL589826.1, AL589826.2, POU3F2, FBXL4, AL078603.1, MIR548AI, BDH2P1, FAXC, COQ3, PNISR, AL513550.1, USP45, TSTD3, Y_RNA, CCNC, AL137784.1.
- chr6:99,993,934–100,890,338, 11 genes, copy number 9: MCHR2-AS1, NPM1P38, AL080285.2, PRDX2P4, AL080285.1, SIM1, SIM1-AS1, ASCC3, Z86062.1, AL133338.1, AL133338.2.
- chr6:102,078,872–107,133,170, 53 genes, copy number 10–38: AP002530.1, AL357139.2, AL357139.1, Z98755.1, AL591387.1, AL590608.1, R3HDM2P2, NPM1P10, AL357522.1, AL356967.1, HACE1, RNU6-897P, AL357315.1, AL357315.2, LIN28B-AS1, LIN28B, RNU6-1106P, BVES, BVES-AS1, POPDC3, PREP, AL133406.2, AL133406.1, RPL35P3, AL096794.1, LINC02836, Z97206.1, AL591518.1, RN7SKP211, PRDM1, ATG5, AL022067.1, U4, RN7SL47P, RNU6-344P, AL356859.1, CRYBG1, Y_RNA, RNA5SP211, AL109920.1, Y_RNA, RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1, BEND3, RNU6-1299P.
- chr6:107,192,300–107,230,152, 2 genes, copy number 38: AL591516.1, RPS24P12.
- chr7:70,972–3,198,256, 83 genes, copy number 7 (broad region; genes not listed).
- chr7:153,715,074–159,233,377, 89 genes, copy number 5 (broad region; genes not listed).
- chr8:38,176,533–145,066,685, 1,668 genes, copy number 5–20 (broad region; genes not listed).
- chr12:91,140,484–91,193,942, 2 genes, copy number 7: DCN, AC007115.1.
- chr15:93,230,034–93,569,483, 1 gene, copy number 5 (within-gene range 4–5): AC091078.1.
- chr15:93,416,850–98,293,199, 79 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr17:42,810,134–56,511,659, 464 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr18:20,946,906–23,026,488, 48 genes, copy number 6 (within-gene range 2–6): ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741.
- chr19:27,638,483–58,605,223, 1,686 genes, copy number 5–13 (broad region; genes not listed).
- chr20:26,132,887–64,313,132, 923 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
